Gene-level copy-number profile of tumor specimen TCGA-25-2404-01A from TCGA case TCGA-25-2404, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 38.8 years (14,184 days).
Specimen TCGA-25-2404-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b71494e2-1f72-45de-bf6b-2f5ae0b0c1f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2404-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33f9bad4-5159-4867-b832-536ba47bcdc1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,118; copy number 2: 16,791; copy number 3: 27,402; copy number 4: 11,855; copy number 5: 904; copy number 6: 56; copy number 7: 629; copy number 8: 886; copy number 9: 2; copy number 11: 6; copy number 16: 43; copy number 18: 123.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2404-01A-01D-0704-01): tumor purity 0.63, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,689 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:165,772,904–198,222,513, 629 genes, copy number 7 (broad region; genes not listed).
- chr8:90,058,608–145,066,685, 886 genes, copy number 8 (broad region; genes not listed).
- chr12:24,902,309–26,833,194, 43 genes, copy number 16 (within-gene range 6–16): AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1.
- chr19:29,606,283–29,841,818, 6 genes, copy number 11 (within-gene range 4–11): POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2.
- chr19:37,907,208–40,285,536, 123 genes, copy number 18 (within-gene range 3–18) (broad region; genes not listed).
- chr20:15,552,157–15,619,819, 2 genes, copy number 9: AL121584.1, ENSAP1.

Autosomal genes at a single copy (total copy number 1): 1,118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
